Surgical pathology report (de-identified scan), TCGA case TCGA-AJ-A4ZG, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site International Genomics Conosrtium, specimen TCGA-AJ-A4ZG-01A (Primary Tumor).

[page 1 of 3]
Sex: Female

SURGICAL PATHOLOGY REPORT

DIAGNOSIS:

DIAGNOSIS:

A. Left ovary and fallopian tube, excision:

Metastatic carcinoma present in ovary, fallopian tube negative for malignancy.

B. Right ovary and fallopian tube, excision:

Metastatic carcinoma present in ovary and fallopian tube.

ICD-0-3

C. Appendix epiploic, excision:

Metastatic carcinoma.

carcinoma, serous, NOS 8441/3

Site: Endometrium C54.1

D. Uterus, hysterectomy:

Tumor Characteristics:

1. Histologic type: Serous carcinoma.
2. Histologic grade: High-grade.
3. Tumor site: Endometrium.
4. Tumor size: 5.5 by 3.5 cm.
5. Myometrial invasion: Tumor extends 1.0 cm into a 3.2 cm thick myometrium.
6. Involvement of cervix: Tumor present in cervical stromal tissue.
7. Extent of involvement of other organs: See other parts of case.
8. Lymphovascular space invasion: Focally present.

Surgical Margin Status:

1. Margins uninvolved:
- Vaginal margin (0.1 cm).
- Deep margin: Tumor not definitively at deep margin of resection but serosal uterine implants are present.
2. Margins involved: No definitive margin involvement identified.
- Lymph Node Status:
1. No lymph nodes present.
- Other:
1. Other significant findings: Tumor present in vaginal tissue.
2. pTNM stage: pT3b, NX, M1 (FIGO IVB).

hw
11/4/12

E. Omentum, excision:

Metastatic carcinoma.

F. Left ovarian artery and vein, excision:

Metastatic carcinoma.

G. Right ovary artery and vein, excision:

Negative for malignancy.

H. Appendix, appendectomy:

Metastatic carcinoma.

I. Liver biopsy:

Prominent cautery artifact.
Malignancy not identified.

J. Peritoneal nodule, biopsy:

Negative for malignancy.

COMMENTS:

[page 2 of 3]
Appropriately controlled immunohistochemical stains performed on blocks A3 and B9 for WT1 and P53 show tumor cells diffusely positive for P53 while being predominantly negative for WT1. These findings are most compatible with a primary endometrial serous carcinoma with metastatic spread to the adnexa.

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis: Mass, ascites, vaginal nodule

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

- A. Left tube and ovary
- B. Right tube and ovary
- C. Appendix epiploic
- D. Uterus, cervix
- E. Omentum
- F. Left ovarian artery and vein NOS
- G. Right ovarian artery and vein NOS
- H. Appendix
- I. Liver biopsy
- J. Peritoneal nodule

SPECIMEN DATA

GROSS DESCRIPTION:

A. The first container A is received in formalin labeled left tube and ovary. The specimen consists of an ovary with attached fallopian tube. The ovary measures 6.5 x 4.0 x 3.0 cm. The surface is gray tan and nodular. On sectioning the cut surface is yellow to gray tan with fibrous areas. There is a cyst measuring 1.0 cm containing a small amount of clear fluid. The cyst lining displays excrescences measuring up to 0.5 cm. The surrounding ovarian stroma is yellow to gray, fibrous with corpus luteum measuring up to 3.0 cm containing yellow tan fibrinous material. The fallopian tube measures 5.0 cm in length and 0.5 cm in diameter. The surface is gray tan to brown tan. On sectioning, there are no material lesions identified within the lumen. The fallopian tube appears grossly unremarkable. Representative sections are submitted in cassettes labeled as follows: Sections from the ovary displaying the cyst containing the excrescences blocks 1 and 2; sections from the cyst displaying the fibrous material in blocks 3 and 4; fallopian tube block 5.

B. The second container B is received in formalin labeled right tube ovary. The specimen consists of an ovary with attached fallopian tube. The ovary measures 6.5 x 4.0 x 3.0 cm. The surface is gray tan to brown tan with hemorrhagic adhesions. On sectioning there is a yellow gray lobular mass measuring 4.0 x 4.0 x 2.0 cm identified. The fallopian tube measures 5.0 cm in length and up to 0.7 cm in diameter. The surface is gray tan to brown tan. On sectioning there is no material within the lumen. Near the fimbriated end there is gray tan firm fibrous tissue attached to the fimbriated end measuring 1.5 x 1.5 x 1.0 cm that has a gray tan fibrous cut surface. Representative sections are submitted in cassettes labeled as follows: Sections from the ovary blocks 1-5; sections from fallopian tube in blocks 6 and 7.

C. The third container C is received in formalin labeled appendix epiploic. The specimen consists of a piece of yellow brown fibroadipose tissue displaying hemorrhage, 2.0 x 1.0 x 1.0 cm. On sectioning the cut surface reveals yellow gray tan fibrous tissue within the yellow tan fatty fibroadipose tissue. Representative sections are submitted in a single cassette.

D. The fourth container D is received in formalin labeled uterus, cervix. The specimen consists of a previously bisected uterus with attached cervix. The uterus measures 7.2 x 7.5 x 5.0 cm and weighs 133 grams. The serosal surface of the uterus is gray tan to brown tan. There is marked hemorrhage and adhesions. The serosal surface is inked. Sections from the parametrium have been taken. The cervix measures 8.0 cm in length and 4.5 cm in diameter. There is attached vaginal mucosa that is gray tan to brown tan with hemorrhage and focal nodular surface that involves a 2.5 x 2.0 cm area of the vaginal mucosa. The ectocervical mucosa is gray tan to brown tan hemorrhagic. The endocervical canal is gray tan to brown tan with nodular areas measuring up to 0.5 cm. The lesions extend into the cervical wall approximately 1.2 cm deep, are 0.5 cm from the deep resected margin, come within 0.1 cm of the resected vaginal margin. The endometrial cavity measures 5.0 cm in length and 5.0 cm from cornu to cornu and is lined by a gray brown shaggy mass measuring 5.5 x 3.5 cm extending to the lower uterine segment of almost the entire cavity. On sectioning the mass extends into the underlying myometrium approximately 1 cm into a 3.2 cm thick myometrium. The myometrium is gray tan and trabecular. Within the myometrium there is a white tan whorled intramural mass beneath the endometrial lesion that is 2.2 cm in greatest dimension that has a white tan whorled appearance. There is no evidence of hemorrhage or necrosis. Received with the specimen are three cassettes, one yellow, one green, one blue labeled as follows: Cervix vaginal mucosa from 12:00 to 3:00 in blocks 1 and 2; 3:00 to 6:00 in blocks 3 and 4; 6:00 to 9:00 in blocks 5 and 6; 9:00 to 12:00 in blocks 7 and 8; full thickness sections from the endometrial lesion bisected as follows: One cross section in blocks 9 and 10; one cross section in blocks 11 and 12; one cross section in blocks 13 and 14; one cross section in blocks 15 and 16; lower uterine segment block 17; left parametrium block 18; right parametrium block 19.

E. The fifth container E is received in formalin labeled omentum. The specimen consists of a piece of yellow brown lobular fibroadipose omentum tissue displaying hemorrhage measuring 21 x 10 x 2.0 cm. Sectioning, there are white tan fibrotic nodules measuring from 0.3 to 0.8 cm identified of less than 10% of the surface area of the specimen submitted. Representative sections of the nodules are submitted in two cassettes labeled

[page 3 of 3]
F. The sixth container F is received in formalin labeled right ovarian artery and vein. The specimen consists of two gray vascular structures measuring 4.0 cm length and up to 1.0 cm in diameter. The surface is gray tan to brown tan. At one end surrounding the vessels there is gray fibrotic tissue that comes within 0.4 cm of the resected margin of the vessel. Representative sections are submitted in a single cassette labeled

G. The seventh container G is received in formalin labeled right ovarian artery and vein. The specimen consists of vessel measuring 3.0 cm in length and 1.0 cm in diameter. The surface is gray tan to brown tan. Within the center there is gray fibrotic tissue surrounding the vessels. Representative sections are submitted in cassette labeled

H. The eighth container H is received in formalin labeled appendix. The specimen consists of an appendix that measures 7.6 cm in length and 1.0 cm in diameter with attached periappendiceal fat that is yellow to brown tan with slight hemorrhage. The surface of the appendix is gray tan to brown tan with hemorrhage and adhesions. There is no perforation noted. On sectioning the wall is thickened measuring 0.5 cm. There is a small amount of yellow brown material within the lumen. Within the periappendiceal fat adjacent to the wall there is focal gray tan fibrotic nodule measuring 0.2 cm. The nodule does not appear to invade into the appendix. The proximal resected margin of the appendix has been inked. Representative sections are submitted in a single cassette labeled

I. The ninth container I is received in formalin labeled liver biopsy. The specimen consists of a piece of yellow brown soft tissue measuring 0.5 x 0.4 x 0.2 cm. The specimen is entirely submitted in a single cassette labeled

J. The tenth container J is received in formalin labeled peritoneal nodule. The specimen consists of a piece of yellow gray soft tissue that measures 0.7 x 0.5 x 0.4 cm. The specimen is entirely submitted in a single cassette labeled

Diagnostic Discrepancy		
Reviewed in (check):	Date reviewed: 11/27/12	

Source: NCI Genomic Data Commons file 9ec5ea6f-8681-4bf1-827c-04b6455b9c93 (TCGA-AJ-A4ZG.639D98FB-EFCA-4FDC-A4A0-308951C91710.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).